Somatic mutation profile of tumor specimen TCGA-CM-5862-01A (aliquot TCGA-CM-5862-01A-01D-1650-10) from TCGA case TCGA-CM-5862, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 80.7 years (29,493 days).
Specimen TCGA-CM-5862-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8036f627-9675-4d29-bc62-70513910dbb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-5862-10A (Blood Derived Normal), aliquot TCGA-CM-5862-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1adb77d5-05ca-4783-aa81-c03f90cbd29c

The open-access MAF lists 92 somatic variants for this specimen: 65 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 58, Silent 27, Splice Site 3, Nonsense Mutation 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2663G>A p.R888Q | Missense Mutation (SNP) | VAF 69/219 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs776681643, COSV55391670, COSV99855011; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 65/77 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACER1 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.211); catalogued as rs1024929658, COSV56834790; called by muse, varscan2
- AK7 | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV50870491; called by muse, mutect2, varscan2
- AKAP12 | c.3251C>A p.S1084* | Nonsense Mutation (SNP) | VAF 23/69 reads (33%) | catalogued as COSV53583415; called by muse, mutect2, varscan2
- AMPH | c.510A>C p.E170D | Missense Mutation (SNP) | VAF 68/390 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100342195; called by muse, mutect2
- AR | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 51/79 reads (65%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV101017615, COSV101018342; called by muse, mutect2, varscan2
- ARHGEF11 | c.2582A>G p.E861G | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100168629; called by muse, mutect2, varscan2
- ARL11 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); catalogued as rs374531869, COSV56292304; called by muse, mutect2, varscan2
- ASTN1 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 72/240 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs758946441, COSV99921788; called by muse, varscan2
- BBS2 | c.152A>G p.H51R | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV55329003; called by muse, mutect2
- CD163L1 | c.3536T>G p.I1179S | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100550109; called by muse, mutect2, varscan2
- CDH9 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 152/174 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1227025606, COSV50250823, COSV50509224; called by muse, mutect2, varscan2
- CHGB | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as rs369985726; called by muse, varscan2
- CIT | c.2714G>A p.R905H | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1365907131, COSV99949720; called by muse, mutect2, varscan2
- COLEC11 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1196317336, COSV52595246; called by muse, mutect2, varscan2
- CSF2RB | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV53261435; called by muse, mutect2, varscan2
- DAPK2 | c.54G>C p.K18N | Missense Mutation (SNP) | VAF 120/297 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV56048842; called by muse, mutect2
- DGKI | c.2908G>A p.G970S | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as rs1019720808, COSV55934819; called by muse, mutect2
- EPHB1 | c.963C>T p.S321= | Splice Region (SNP) | VAF 42/93 reads (45%) | catalogued as rs746454977, COSV67673009; called by muse, mutect2, varscan2
- ESYT3 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs765784956, COSV101272683; called by muse, varscan2
- FAM124A | c.790C>T p.R264C (on ENST00000322475 / NM_001242312.2; = p.R300C on NM_145019.4) | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54476071; called by muse, mutect2, varscan2
- FLG | c.4310G>A p.R1437H | Missense Mutation (SNP) | VAF 175/510 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs367594853; called by muse, mutect2, varscan2
- FLT1 | c.3898G>A p.V1300I | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs750346448, COSV56721559; called by muse, mutect2, varscan2
- GABRB3 | c.682+2T>G p.X228_splice | Splice Site (SNP) | VAF 23/61 reads (38%) | catalogued as COSV100160052; called by muse, mutect2, varscan2
- GNRH1 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 95/127 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV52382744; called by muse, mutect2, varscan2
- IDO2 | c.1160T>G p.V387G (on ENST00000389060; = p.V400G on NM_194294.2) | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV100584767; called by muse, mutect2, varscan2
- IGSF9B | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.833); catalogued as rs746839644, COSV100318053, COSV58073424; called by muse, mutect2, varscan2
- LNX1 | c.1157A>C p.K386T (on ENST00000263925 / NM_001126328.3; = p.K290T on NM_032622.2) | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55792411; called by muse, mutect2, varscan2
- LOXL4 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs779922908, COSV99583895; called by muse, mutect2, varscan2
- LRRC32 | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as rs770158787, COSV52631965, COSV99036032; called by muse, varscan2
- MYO5A | c.4585G>C p.V1529L | Missense Mutation (SNP) | VAF 105/239 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.39); catalogued as COSV62559054; called by muse, mutect2, varscan2
- NES | c.3680C>T p.P1227L | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs746890108, COSV63963149; called by muse, mutect2, varscan2
- NTRK1 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 58/205 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs540521894, COSV62324041; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NXF3 | c.1053-2A>C p.X351_splice | Splice Site (SNP) | VAF 104/112 reads (93%) | catalogued as COSV67705353; called by muse, mutect2
- OR10A7 | c.238A>C p.K80Q | Missense Mutation (SNP) | VAF 214/510 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.362); catalogued as COSV100406569; called by mutect2, varscan2
- OR9Q2 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.066); catalogued as COSV61112887; called by muse, mutect2
- PABPC5 | c.560C>A p.A187E | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs779221642, COSV57043514; called by muse, mutect2, varscan2
- PARP14 | c.2629G>A p.V877M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752297915, COSV71734343, COSV71735672; called by muse, mutect2, varscan2
- PCDH7 | c.1105G>A p.V369I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as COSV62344087; called by muse, mutect2, varscan2
- PKD1 | c.12761C>T p.A4254V (on ENST00000262304 / NM_001009944.3; = p.A4253V on NM_000296.4) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.055); catalogued as rs144474078; called by muse, mutect2
- POU3F4 | c.379A>G p.S127G | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100937140, COSV64541357; called by muse, mutect2, varscan2
- PXDN | c.2162C>T p.S721L | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs377269649; called by muse, mutect2, varscan2
- PYGL | c.1310G>A p.S437N | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV53589156; called by muse, mutect2, varscan2
- RDH8 | c.986G>A p.R329Q (on ENST00000651512; = p.R309Q on NM_015725.4) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.009); catalogued as rs542025894, COSV50679205; called by muse, mutect2, varscan2
- RYR3 | c.4466G>A p.R1489Q | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370542262; called by muse, mutect2, varscan2
- SLCO4A1 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs567670164, COSV53894472; called by muse, mutect2, varscan2
- SNED1 | c.1781C>T p.T594M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs751414477, COSV60023360; called by muse, mutect2, varscan2
- SPATA31D1 | c.4490G>C p.R1497T | Missense Mutation (SNP) | VAF 59/187 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.947); catalogued as COSV61202085; called by muse, mutect2, varscan2
- SPTA1 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 120/190 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs772799574, COSV63749744, COSV63759526; called by muse, varscan2
- TP73 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs757455947, COSV60705887; called by muse, mutect2, varscan2
- TRAK2 | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 128/195 reads (66%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV60272821; called by muse, mutect2, varscan2
- TRPM5 | c.2926G>A p.A976T | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772292156, COSV50144391; called by muse, mutect2, varscan2
- TTN | c.25657C>A p.L8553I (on ENST00000591111; = p.L7626I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/353 reads (28%) | PolyPhen benign (0.017); catalogued as COSV60387183; called by muse, mutect2, varscan2
- TUBA3C | c.491A>C p.K164T | Missense Mutation (SNP) | VAF 154/984 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.412); catalogued as COSV101262864, COSV67139180; called by muse, mutect2, varscan2
- TYRP1 | c.565G>T p.V189F | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66358590; called by muse, mutect2, varscan2
- UHRF1BP1 | c.3715C>G p.P1239A | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99511926; called by muse, mutect2
- USP9X | c.7218+1G>A p.X2406_splice | Splice Site (SNP) | VAF 333/380 reads (88%) | catalogued as COSV61066273; called by muse, mutect2, varscan2
- WDR64 | c.3091G>A p.V1031I | Missense Mutation (SNP) | VAF 102/170 reads (60%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs139639842; called by muse, mutect2, varscan2
- ZAP70 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as COSV53853664; called by muse, mutect2, varscan2
- ZNF507 | c.976A>G p.I326V | Missense Mutation (SNP) | VAF 76/157 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs756072741, COSV61333649; called by muse, mutect2, varscan2
- ZNF7 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 114/165 reads (69%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57385628; called by muse, mutect2, varscan2
- ZNF721 | c.73A>T p.R25* (on ENST00000338977; = p.R37* on NM_133474.4) | Nonsense Mutation (SNP) | VAF 151/616 reads (25%) | catalogued as COSV59097710; called by muse, mutect2, varscan2
- IGKV6D-41 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 353/578 reads (61%) | SIFT tolerated (0.92); PolyPhen benign (0.164); called by muse, varscan2
- SET | c.275del p.P92Qfs*5 (on ENST00000372692 / NM_001374326.1; = p.P79Qfs*5 on NM_003011.4) | Frame Shift Del (DEL) | VAF 152/523 reads (29%) | called by mutect2, pindel, varscan2
- BTBD2 | c.1317C>A p.G439= | Silent (SNP) | VAF 43/70 reads (61%) | catalogued as rs766740895, COSV55307870, COSV99724764; called by muse, mutect2, varscan2
- CACNG6 | c.228C>T p.C76= | Silent (SNP) | VAF 14/18 reads (78%) | catalogued as rs1459324474, COSV53168622; called by muse, mutect2, varscan2
- CHD7 | c.4623T>C p.D1541= | Silent (SNP) | VAF 402/666 reads (60%) | catalogued as rs754019726, COSV71115131; called by muse, mutect2, varscan2
- COL4A6 | c.3240C>T p.S1080= | Silent (SNP) | VAF 92/106 reads (87%) | catalogued as COSV100564158; called by muse, mutect2, varscan2
- DCP1A | c.1707C>T p.Y569= | Silent (SNP) | VAF 118/150 reads (79%) | catalogued as rs1553685297, COSV53691110; called by muse, mutect2, varscan2
- DEPDC4 | c.46T>C p.L16= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV54554567; called by muse, mutect2, varscan2
- DOT1L | c.1320C>T p.T440= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs545805803, COSV67113810; called by muse, mutect2, varscan2
- EBF3 | c.420C>A p.V140= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV62473502, COSV62482602; called by muse, mutect2, varscan2
- EXD2 | c.1284C>T p.S428= (on ENST00000312994 / NM_001193362.1; = p.S303= on NM_018199.3) | Silent (SNP) | VAF 97/134 reads (72%) | catalogued as COSV57282556; called by muse, mutect2, varscan2
- GALNT18 | c.1248C>T p.H416= | Silent (SNP) | VAF 50/160 reads (31%) | catalogued as rs752489000, COSV57158235; called by muse, mutect2, varscan2
- GNAT2 | c.966C>T p.H322= | Silent (SNP) | VAF 27/263 reads (10%) | catalogued as COSV100655838; called by muse, mutect2, varscan2
- IMPG1 | c.213C>T p.S71= | Silent (SNP) | VAF 218/685 reads (32%) | catalogued as rs112629451; called by muse, varscan2
- LILRA4 | c.378C>T p.S126= | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as rs769153231, COSV52490469; called by muse, mutect2
- LMF2 | c.732C>T p.F244= | Silent (SNP) | VAF 48/109 reads (44%) | catalogued as rs139963184; called by muse, varscan2
- MKI67 | c.3162G>A p.T1054= | Silent (SNP) | VAF 266/571 reads (47%) | catalogued as rs1395550754, COSV64073743; called by muse, mutect2, varscan2
- NUP85 | c.324C>T p.V108= | Silent (SNP) | VAF 44/207 reads (21%) | catalogued as COSV55467219; called by muse, mutect2, varscan2
- OR2T35 | c.75C>T p.P25= | Silent (SNP) | VAF 54/156 reads (35%) | catalogued as rs1468809895, COSV100442281; called by muse, varscan2
- PCDHA4 | c.1509G>A p.A503= | Silent (SNP) | VAF 42/79 reads (53%) | catalogued as COSV100793144; called by muse, mutect2, varscan2
- PTPRC | c.708T>C p.T236= | Silent (SNP) | VAF 96/340 reads (28%) | catalogued as rs1488971685, COSV100722683; called by muse, mutect2
- RNF148 | c.822A>G p.L274= | Silent (SNP) | VAF 101/338 reads (30%) | catalogued as COSV57388743; called by muse, mutect2, varscan2
- SACS | c.993T>C p.F331= | Silent (SNP) | VAF 70/496 reads (14%) | catalogued as COSV101207458; called by muse, mutect2, varscan2
- SDSL | c.480A>C p.A160= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV61885459; called by muse, mutect2
- SIGLEC7 | c.87G>A p.T29= | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as rs1355670634, COSV58318151; called by muse, mutect2, varscan2
- SLC12A5 | c.3249C>T p.I1083= (on ENST00000454036 / NM_001134771.2; = p.I1060= on NM_020708.5) | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as COSV99275603; called by mutect2, varscan2
- SORCS3 | c.1119C>T p.I373= | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as rs768587661, COSV63805566, COSV63827140; called by muse, mutect2, varscan2
- USP49 | c.1785C>T p.T595= | Silent (SNP) | VAF 47/163 reads (29%) | catalogued as COSV51901494; called by muse, mutect2, varscan2
- ZNF536 | c.2178C>T p.G726= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs372631694, COSV100835317, COSV62831659; called by muse, mutect2, varscan2
